Somatic mutation profile of tumor specimen 0DF86V from CCDI case PBBRWJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.5 years (6,030 days).
Specimen 0DF86V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef7983a-9663-4760-91ea-2cd893fc9b58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF86W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/220b09d0-2c74-41c7-a642-5fa5a1f88f0c

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.973C>T p.R325C (on ENST00000399959; = p.R326C on NM_001356.5) | Missense Mutation (SNP) | VAF 294/394 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1555953548, COSV67863531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 226/611 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 89/328 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2, varscan2
- ABCA4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 199/587 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769541140; called by muse, mutect2, varscan2
- CCDC198 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99371151; called by muse, mutect2, varscan2
- CFAP47 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 132/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372454366, COSV52890279; called by muse, mutect2, varscan2
- FBXO33 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 275/765 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1429846931; called by muse, mutect2, varscan2
- IQCM | c.208A>C p.K70Q | Missense Mutation (SNP) | VAF 127/886 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.995); catalogued as rs565157282; called by muse, mutect2, varscan2
- KCNV1 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV52089778, COSV99819487; called by muse, mutect2, varscan2
- NCKAP5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 338/885 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748072988; called by muse, mutect2, varscan2
- PTCH1 | c.3168+1G>T p.X1056_splice | Splice Site (SNP) | VAF 565/734 reads (77%) | catalogued as COSV59468520; called by muse, mutect2, varscan2
- SUPT16H | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 186/578 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53526029, COSV99359814; called by muse, mutect2, varscan2
- DDX3X | c.1283C>A p.S428* (on ENST00000399959; = p.S429* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 15/419 reads (4%) | called by muse, mutect2
- RUVBL1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 58/489 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SCN4A | c.5030_5031insA p.D1678Gfs*13 | Frame Shift Ins (INS) | VAF 42/318 reads (13%) | called by mutect2, varscan2
- SLMAP | c.535del p.E179Nfs*8 | Frame Shift Del (DEL) | VAF 180/456 reads (39%) | called by mutect2, varscan2
- ST18 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 112/259 reads (43%) | called by muse, mutect2, varscan2
- TLR3 | c.1451G>C p.R484P | Missense Mutation (SNP) | VAF 187/507 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZSWIM9 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ATP8A2 | c.2466C>T p.G822= | Silent (SNP) | VAF 136/331 reads (41%) | catalogued as rs764838044, COSV54953343; called by muse, mutect2, varscan2
- CD300LF | c.519C>T p.A173= | Silent (SNP) | VAF 216/628 reads (34%) | catalogued as rs1465192444; called by muse, mutect2, varscan2
- CHD9 | c.3225A>G p.K1075= | Silent (SNP) | VAF 94/807 reads (12%) | called by muse, mutect2, varscan2
- CRIM1 | c.2076G>A p.T692= | Silent (SNP) | VAF 151/421 reads (36%) | catalogued as rs912260044; called by muse, mutect2, varscan2
- KIF26A | c.1821G>A p.T607= | Silent (SNP) | VAF 143/380 reads (38%) | catalogued as rs779539835; called by muse, mutect2, varscan2
- LRPPRC | c.300T>C p.I100= | Silent (SNP) | VAF 250/708 reads (35%) | called by muse, mutect2, varscan2
- LRRK2 | c.2274G>T p.V758= | Silent (SNP) | VAF 250/706 reads (35%) | called by muse, mutect2, varscan2
- NAA50 | c.129C>T p.G43= | Silent (SNP) | VAF 40/890 reads (4%) | called by muse, mutect2
- ROCK1 | c.1161C>T p.F387= | Silent (SNP) | VAF 284/752 reads (38%) | catalogued as rs376920401; called by muse, mutect2, varscan2
- COPE | c.444-17del | Intron (DEL) | VAF 56/176 reads (32%) | called by mutect2, varscan2
- WFS1 | c.713-81G>A | Intron (SNP) | VAF 23/82 reads (28%) | catalogued as rs773845228; called by muse, mutect2, varscan2
